Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AANR, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Southern California, specimen TCGA-XE-AANR-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATH []

Order

Order Clinic:

Order Dx:

Specimen

CASE NO.:

GROSS EXAM DATE:

PHYSICIAN & PAGER #:

-- CONCLUSION/DIAGNOSTIC CODE -----
NON-ROUTINE

-- REPORT -----

DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

1. SEMINOMA (9 cm), right testis, right radical orchiectomy. (See note)
2. LYMPHOVASCULAR INVASION OF SMALL VESSELS NOTED.
3. NO INVASION OF EPIDIDYMIS NOTED.
4. TUMOR LIMITED TO TESTIS.
5. MARGINS FREE OF TUMOR.
6. pT2NXMX.
7. TESTICULAR TISSUE WITH TUBULAR ATROPHY AND WITHOUT EVIDENCE OF SPERMATOGENESIS.

GROSS DESCRIPTION:

The specimen is received unfixed labeled with the patient's name, number and "right testicular mass." It consists of a 290 gram orchiectomy specimen including 9.5 x 7 x 6 cm testis and 10 cm in length and 1.5 cm in diameter spermatic cord. Testis reveals white-tan to brown-tan multinodular tumor, focal areas of hemorrhage and necrosis. No normal testicle tissue identified. There is no gross involvement of the tunica albuginea. The epididymis appears obliterated by tumor. The spermatic cord consists of vas deferens, arteries and veins and is unremarkable.

SUMMARY OF CASSETTES:

- Cassettes 1 to 5 - tumor.
Cassette 6 - tumor and tunica vaginalis.
Cassette 7 - base of epididymis.
Cassette 8 - spermatic cord resection margin.
Cassette 9 - spermatic cord mid portion.

ICD O-3

Seminoma NOS 9061/3

Site (R) Testis NOS C62.9

3/31/14

[page 2 of 2]
Loc:
Dr.

-- REPORT --

Cassette 10 - spermatic cord peritesticular portion.
R10.

Source: NCI Genomic Data Commons file 0dab3d02-3595-43dc-96a1-f63ce3961ea8 (TCGA-XE-AANR.36298858-A815-4301-B3D4-8F6D12C90889.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).